Somatic mutation profile of tumor specimen C3N-00953-01 (aliquot CPT0065220009) from CPTAC case C3N-00953, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 41.4 years (15,137 days).
Specimen C3N-00953-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6162c478-bd31-49de-a279-49fa6dc7f294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00953-31 (Blood Derived Normal), aliquot CPT0070680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc41693e-3749-4cf7-92f1-31caef2d6b6c

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Intron 6, Frame Shift Del 5, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.3028T>C p.C1010R | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs760212862; called by muse, mutect2
- FAM133A | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as rs1476222624; called by muse, mutect2, varscan2
- FGFR3 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs774934127, COSV99601289; called by muse, mutect2, varscan2
- HERC1 | c.13366A>G p.M4456V | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs773560667; called by muse, mutect2, varscan2
- PCDHA11 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 128/756 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV56484777; called by muse, mutect2, varscan2
- PCDHGB1 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 102/589 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs926788481; called by muse, mutect2, varscan2
- PRAG1 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV58164802; called by muse, mutect2, varscan2
- PRAMEF8 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 170/1544 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1347550555; called by muse, mutect2, varscan2
- PRKCG | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 168/744 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54730150; called by muse, mutect2, varscan2
- RCN1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs377179238; called by muse, mutect2, varscan2
- RTF1 | c.602A>C p.E201A | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101047824, COSV67478521; called by muse, mutect2, varscan2
- VHL | c.349dup p.W117Lfs*15 | Frame Shift Ins (INS) | VAF 60/251 reads (24%) | catalogued as COSV56547585; called by mutect2, pindel, varscan2
- ADAMTS1 | c.2566T>A p.S856T | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ATP13A1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); called by muse, mutect2
- BAP1 | c.1009A>T p.K337* | Nonsense Mutation (SNP) | VAF 67/199 reads (34%) | called by muse, mutect2, varscan2
- DNAJC14 | c.841del p.S281Afs*18 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by mutect2, pindel, varscan2
- DPH2 | c.923del p.Q308Rfs*32 | Frame Shift Del (DEL) | VAF 56/235 reads (24%) | called by mutect2, pindel, varscan2
- DPP10 | c.89_90del p.R30Kfs*30 | Frame Shift Del (DEL) | VAF 36/186 reads (19%) | called by pindel, varscan2*
- EHBP1L1 | c.1375C>G p.P459A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- FMNL2 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); called by muse, mutect2
- GOLGB1 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.5G>C p.R2P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- MAGEA12 | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MKLN1 | c.862T>A p.F288I | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MMS19 | c.928T>G p.F310V | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MOG | c.728T>A p.L243Q | Missense Mutation (SNP) | VAF 69/460 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- OR2C1 | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2
- PCDH15 | c.99A>T p.K33N | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PDPR | c.1594T>A p.F532I | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- RNF11 | c.215A>C p.Q72P | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SMG1 | c.2342G>T p.S781I | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SPTA1 | c.257A>T p.N86I | Missense Mutation (SNP) | VAF 34/439 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- TIMM23B | c.530del p.L177Wfs*28 | Frame Shift Del (DEL) | VAF 52/290 reads (18%) | called by mutect2, pindel, varscan2
- UNG | c.733A>G p.N245D (on ENST00000242576 / NM_080911.3; = p.N236D on NM_003362.4) | Missense Mutation (SNP) | VAF 113/567 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFY | c.174T>A p.D58E | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF600 | c.393_400del p.Q132Yfs*3 | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | called by mutect2, pindel, varscan2
- DLG4 | c.1794C>T p.F598= (on ENST00000399506 / NM_001321075.3; = p.F641= on NM_001365.4) | Silent (SNP) | VAF 54/285 reads (19%) | called by muse, mutect2, varscan2
- EGFL8 | c.138G>A p.P46= | Silent (SNP) | VAF 63/331 reads (19%) | catalogued as rs575900965; called by muse, mutect2, varscan2
- MIGA2 | c.264C>T p.P88= | Silent (SNP) | VAF 67/354 reads (19%) | catalogued as rs538683313; called by muse, mutect2, varscan2
- PCDHB16 | c.1596C>T p.G532= | Silent (SNP) | VAF 89/703 reads (13%) | catalogued as rs782139928, COSV53370404; called by muse, mutect2, varscan2
- RCOR2 | c.192C>T p.P64= | Silent (SNP) | VAF 51/234 reads (22%) | catalogued as rs754428923; called by muse, mutect2, varscan2
- RXFP3 | c.714G>A p.T238= | Silent (SNP) | VAF 63/340 reads (19%) | catalogued as rs547132118, COSV57508081; called by muse, mutect2, varscan2
- SMG1 | c.2343C>T p.S781= | Silent (SNP) | VAF 20/159 reads (13%) | called by muse, mutect2, varscan2
- STYXL2 | c.423C>T p.V141= | Silent (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- ZNF99 | c.420C>G p.T140= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV68055380; called by muse, mutect2
- COL18A1 | c.3928+690G>C | Intron (SNP) | VAF 86/384 reads (22%) | catalogued as rs774218242, COSV60587663; called by mutect2, varscan2
- DCLRE1CP1 | n.315G>A | RNA (SNP) | VAF 108/682 reads (16%) | called by muse, mutect2, varscan2
- FANCC | c.*26C>T | 3'UTR (SNP) | VAF 64/302 reads (21%) | catalogued as rs770935196; called by muse, mutect2, varscan2
- FGFR4 | c.1057+155T>C | Intron (SNP) | VAF 31/672 reads (5%) | called by muse, mutect2
- MALRD1 | c.5030-2387G>T | Intron (SNP) | VAF 30/183 reads (16%) | catalogued as rs1248619060; called by muse, mutect2, varscan2
- MED25 | c.2147-25C>T | Intron (SNP) | VAF 40/209 reads (19%) | catalogued as rs761720007; called by muse, mutect2, varscan2
- PTBP3 | c.-15G>T | 5'UTR (SNP) | VAF 65/209 reads (31%) | called by muse, mutect2, varscan2
- SCN2A | c.606-108T>G | Intron (SNP) | VAF 24/602 reads (4%) | called by muse, mutect2
- SPINK5 | c.2740-193T>C | Intron (SNP) | VAF 51/365 reads (14%) | catalogued as rs190012161; called by muse, mutect2, varscan2
- ZSWIM8 | c.*208G>C | 3'UTR (SNP) | VAF 42/220 reads (19%) | called by muse, mutect2, varscan2
